Somatic mutation profile of tumor specimen 0DSHT3 from CCDI case PBCHEC, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 10.2 years (3,722 days).
Specimen 0DSHT3: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4d37db8b-f688-462a-85a6-4372e3424bfa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DSHTD (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a2ae0365-7824-49e1-9844-81ca3c7db68c

The open-access MAF lists 9 somatic variants for this specimen: 7 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Intron 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ITGB4 | c.1777C>T p.R593C | Missense Mutation (SNP) | VAF 88/302 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as rs753166262, COSV99563385; called by muse, mutect2, varscan2
- SLC12A7 | c.2912C>T p.P971L | Missense Mutation (SNP) | VAF 126/490 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.018); catalogued as rs373266073; called by muse, mutect2, varscan2
- SPINK5 | c.194C>T p.T65M | Missense Mutation (SNP) | VAF 113/376 reads (30%) | SIFT tolerated (0.52); PolyPhen benign (0.017); catalogued as rs552548594, COSV99806448; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- WDR87 | c.2840G>A p.R947H | Missense Mutation (SNP) | VAF 133/485 reads (27%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.633); catalogued as rs766532444, COSV58203948; called by muse, mutect2, varscan2
- CATSPERE | c.1804G>A p.G602R | Missense Mutation (SNP) | VAF 21/684 reads (3%) | SIFT tolerated (0.31); PolyPhen benign (0.024); called by muse, mutect2
- ELF3 | c.511G>T p.D171Y | Missense Mutation (SNP) | VAF 14/384 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.514); called by muse, mutect2
- NLRP10 | c.1726G>A p.V576I | Missense Mutation (SNP) | VAF 138/602 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- HPS4 | c.707-88G>T | Intron (SNP) | VAF 16/44 reads (36%) | called by mutect2, varscan2
- MED19 | c.571+18T>C | Intron (SNP) | VAF 60/223 reads (27%) | catalogued as rs769928583; called by mutect2, varscan2
